Gene-level copy-number profile of tumor specimen TCGA-AQ-A0Y5-01A from TCGA case TCGA-AQ-A0Y5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.6 years (25,793 days).
Specimen TCGA-AQ-A0Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.80ffdd30-9845-4ee5-8f68-f272c0b0b1f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AQ-A0Y5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f67d704-bfa8-4a26-a4fd-62dc18170e42

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 953; copy number 2: 16,854; copy number 3: 23,105; copy number 4: 14,012; copy number 5: 2,888; copy number 6: 604; copy number 7: 81; copy number 8: 470; copy number 9: 110; copy number 10: 16; copy number 11: 104; copy number 13: 94; copy number 14: 101; copy number 15: 259; copy number 16: 6; copy number 17: 61; copy number 20: 15; copy number 21: 8; copy number 22: 6; copy number 24: 20; copy number 25: 34; copy number 30: 9; copy number 46: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AQ-A0Y5-01A-11D-A14J-01): tumor purity 0.5, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,395 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:19,878,555–39,180,499, 579 genes, copy number 8–15 (within-gene range 2–15) (broad region; genes not listed).
- chr15:40,585,454–42,569,994, 84 genes, copy number 8–15 (broad region; genes not listed).
- chr17:26,981,694–27,058,221, 5 genes, copy number 13: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P.
- chr17:27,651,334–27,894,752, 13 genes, copy number 9–16: NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9.
- chr17:27,930,177–27,930,920, 1 gene, copy number 16: AC005697.3.
- chr17:32,970,376–34,174,964, 14 genes, copy number 15–20 (within-gene range 4–20): SPACA3, ASIC2, AC003687.1, AC008133.2, AC008133.1, AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2.
- chr17:36,684,754–36,726,346, 2 genes, copy number 13: AC243830.3, AC243830.1.
- chr17:39,210,541–40,885,242, 79 genes, copy number 8–25 (broad region; genes not listed).
- chr17:49,223,366–57,850,056, 178 genes, copy number 7–46 (broad region; genes not listed).
- chr17:59,260,748–61,928,016, 79 genes, copy number 7–24 (within-gene range 4–24) (broad region; genes not listed).
- chr17:66,302,613–66,810,743, 3 genes, copy number 14 (within-gene range 4–16): PRKCA, RN7SL735P, PRKCA-AS1.
- chr17:67,717,931–68,763,882, 36 genes, copy number 11: NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2.
- chr20:43,189,998–47,356,889, 156 genes, copy number 9–15 (broad region; genes not listed).
- chr20:50,040,716–50,192,668, 9 genes, copy number 10: TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB.
- chr20:51,596,514–52,670,578, 10 genes, copy number 10–15 (within-gene range 2–15): ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524.
- chr20:52,482,801–52,862,855, 6 genes, copy number 10: AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1.
- chr20:53,544,615–55,075,140, 18 genes, copy number 17–30: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4.
- chr20:57,599,695–59,847,711, 54 genes, copy number 17 (within-gene range 2–17): AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1.
- chr20:59,958,423–62,937,952, 69 genes, copy number 11–20 (within-gene range 2–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 953. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
